Somatic mutation profile of tumor specimen MMRF_1602_1_BM_CD138pos (aliquot MMRF_1602_1_BM_CD138pos_T2_KBS5U_K11930) from MMRF case MMRF_1602, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.7 years (24,375 days).
Specimen MMRF_1602_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2734f01d-312b-4285-b834-9d9f477760c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1602_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1602_1_PB_Whole_C7_KBS5U_K11904; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ac39a10-07b1-4782-97cb-b6a98130a776

The open-access MAF lists 2,367 somatic variants for this specimen: 852 protein-altering or splice-affecting, 377 silent, 1,138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 731, 3'UTR 577, Silent 377, Intron 324, 5'UTR 125, Nonsense Mutation 70, 5'Flank 43, 3'Flank 40, RNA 29, Splice Region 29, Splice Site 11, Frame Shift Del 6.

Variants (750 of 2,367; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7181C>T p.S2394L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs587779861, CM083481, COSV53735356, COSV53772240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TULP1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906836, CM040811, COSV57691729, COSV57693922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.1820C>T p.S607L (on ENST00000326724 / NM_001080395.3; = p.S504L on NM_004920.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749394790; called by muse, mutect2, varscan2
- ABCA12 | c.5360C>T p.S1787F (on ENST00000272895 / NM_173076.3; = p.S1469F on NM_015657.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV55958692; called by muse, mutect2, varscan2
- ABCA8 | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1344465458, COSV52206791; called by muse, mutect2, varscan2
- ABCA8 | c.2720G>A p.R907K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV52206976, COSV99286337; called by muse, mutect2, varscan2
- ABCC10 | c.2898C>G p.F966L (on ENST00000372530 / NM_001198934.2; = p.F938L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99767939; called by muse, mutect2, varscan2
- ABHD1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs138157315; called by muse, mutect2, varscan2
- AC008397.2 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs746619948; called by muse, mutect2, varscan2
- ADAMTS12 | c.2443G>C p.D815H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV61275402; called by muse, mutect2, varscan2
- ADAMTS13 | c.4267G>A p.G1423R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52469835; called by muse, mutect2, varscan2
- ADNP2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs145820490; called by muse, mutect2, varscan2
- AKAP11 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs778530849; called by muse, mutect2, varscan2
- AKR1C4 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.389); catalogued as COSV54125519; called by muse, mutect2
- AKT3 | c.1283C>G p.S428C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55612324; called by muse, mutect2, varscan2
- ALDH1A2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963837318, COSV51083900; called by muse, mutect2, varscan2
- ALG1 | c.15C>G p.C5W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752922461, CM166620; called by muse, mutect2, varscan2
- ANKRD13A | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs918721721; called by muse, mutect2, varscan2
- ANXA4 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867591932; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2, varscan2
- AP5M1 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765813287, COSV55105278; called by muse, mutect2, varscan2
- AQR | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.384); catalogued as COSV99334449; called by muse, mutect2
- ARID1B | c.6581G>C p.R2194T | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs763772159, COSV51681529, COSV51681833; called by muse, mutect2, varscan2
- ARID3C | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200305923; called by mutect2, varscan2
- ARID4B | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as rs755681504, COSV99934915; called by muse, mutect2, varscan2
- ASPM | c.4843C>G p.H1615D | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV99661014; called by muse, mutect2, varscan2
- ATG2A | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV101034777; called by muse, mutect2
- ATM | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as CD000906; called by muse, mutect2, varscan2
- ATM | c.8783G>A p.R2928K | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1555142909; ClinVar: uncertain significance; called by muse, mutect2
- ATN1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63113281; called by muse, mutect2
- ATP13A2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs770576740, COSV58703696; called by muse, mutect2, varscan2
- ATXN3 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 79/276 reads (29%) | PolyPhen benign (0.316); catalogued as rs750833339; called by muse, mutect2, varscan2
- AVPR1A | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV100146771; called by muse, mutect2
- BAG5 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54570508; called by muse, mutect2, varscan2
- BAIAP2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.745); catalogued as rs1427755770, COSV58336461; called by muse, mutect2, varscan2
- BAIAP3 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs1284727949, COSV50104406; called by muse, mutect2, varscan2
- BRD7 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104433567; called by muse, mutect2, varscan2
- BRIP1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51994869; called by muse, mutect2, varscan2
- C14orf39 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as COSV100407882; called by muse, mutect2, varscan2
- C1QTNF4 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs866041290, COSV100209144; called by muse, mutect2, varscan2
- C1orf122 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as COSV65990366; called by muse, mutect2, varscan2
- C1orf87 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64596255; called by muse, mutect2, varscan2
- C4BPA | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757533084, COSV65537583; called by muse, mutect2, varscan2
- CACNA1H | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs977157885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.785G>C p.R262T (on ENST00000324631 / NM_201596.3; = p.R207T on NM_000724.4) | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV56611627; called by muse, mutect2, varscan2
- CAMK2D | c.1389G>C p.Q463H | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV56436050; called by muse, mutect2, varscan2
- CAPN1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs763767864; called by muse, mutect2, varscan2
- CASKIN1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1405879048; called by muse, mutect2, varscan2
- CCDC90B | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs190914109; called by muse, mutect2, varscan2
- CD47 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs867558279, COSV62528376; called by muse, mutect2
- CD8B | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs747895168, COSV58924933; called by muse, varscan2
- CDH11 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV51760547; called by muse, mutect2
- CEACAM18 | c.401-1G>A p.X134_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as rs773327710; called by muse, mutect2, varscan2
- CEP152 | c.3639G>C p.E1213D (on ENST00000380950 / NM_001194998.2; = p.E1157D on NM_014985.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100358891; called by muse, mutect2, varscan2
- CES4A | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs373745989; called by muse, mutect2, varscan2
- CHMP2A | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.636); catalogued as rs770015701; called by muse, mutect2, varscan2
- CHTF8 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV54708324; called by muse, mutect2
- CITED4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1452600945; called by muse, mutect2, varscan2
- CLK3 | c.1225C>T p.R409W (on ENST00000395066 / NM_001130028.1; = p.R261W on NM_003992.4) | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs1159353958; called by muse, mutect2
- CLPSL1 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1445247390, COSV65814730; called by muse, mutect2
- CLVS1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs867676093, COSV57983759, COSV57984678; called by muse, mutect2
- CNST | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs772749691; called by muse, mutect2, varscan2
- CNTRL | c.6875C>G p.S2292C | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs762072857; called by muse, mutect2, varscan2
- COL11A1 | c.4079G>A p.G1360E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362979459, COSV62174307; called by muse, mutect2, varscan2
- COL6A3 | c.3754C>A p.R1252S | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55084047; called by muse, mutect2, varscan2
- CPA4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55983603, COSV55984811; called by muse, mutect2, varscan2
- CPXM1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs769164265, COSV66044985, COSV66045264, COSV66046515; called by muse, mutect2, varscan2
- CRTC3 | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.956); catalogued as rs774703173; called by muse, mutect2, varscan2
- CRY2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99066014; called by muse, mutect2
- CRYL1 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as rs745637739, COSV100004558; called by muse, mutect2, varscan2
- CSNK1A1L | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs775219612, COSV65789844; called by muse, mutect2, varscan2
- CYP26A1 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV56417101; called by muse, mutect2, varscan2
- DACH2 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV100914143; called by muse, mutect2, varscan2
- DALRD3 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs781227318, COSV58246130, COSV58247362; called by muse, mutect2, varscan2
- DDX28 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs369666846; called by muse, mutect2, varscan2
- DDX41 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100286661; called by muse, mutect2
- DIAPH2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 14/19 reads (74%) | catalogued as COSV100232082; called by muse, mutect2, varscan2
- DLX1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs867218613; called by muse, mutect2, varscan2
- DOCK7 | c.6406C>T p.R2136C (on ENST00000635253 / NM_001367561.1; = p.R2105C on NM_033407.3) | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1403524450; called by muse, mutect2
- DPEP2 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.421); catalogued as COSV99263221; called by muse, mutect2, varscan2
- DSCAML1 | c.3106G>C p.E1036Q (on ENST00000321322; = p.E976Q on NM_020693.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as rs1333420258, COSV58397001; called by muse, mutect2, varscan2
- DSP | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1307574877; called by muse, mutect2, varscan2
- DUSP11 | c.319-1G>A p.X107_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99730838; called by muse, mutect2, varscan2
- EDARADD | c.163G>A p.E55K (on ENST00000334232 / NM_145861.4; = p.E45K on NM_080738.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs765466865, COSV100513002; called by muse, mutect2, varscan2
- EIF3A | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs762264416, COSV64960348; called by muse, mutect2, varscan2
- EIF4A3 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV53921849; called by muse, mutect2, varscan2
- ELAC1 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.313); catalogued as rs1175454977; called by muse, mutect2, varscan2
- EML5 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100716170; called by muse, mutect2, varscan2
- EPN1 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321413; called by muse, mutect2
- EPRS1 | c.2672C>G p.S891C | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65099965; called by muse, mutect2
- EPS8 | c.367-1G>C p.X123_splice | Splice Site (SNP) | VAF 29/95 reads (31%) | catalogued as COSV55528370; called by muse, mutect2, varscan2
- EQTN | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs748710071; called by muse, mutect2, varscan2
- ERH | c.3+3G>A | Splice Region (SNP) | VAF 37/70 reads (53%) | catalogued as rs202027027, COSV50362057; called by muse, mutect2, varscan2
- ETV6 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56766946; called by muse, mutect2
- FAM120A | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99465613; called by muse, mutect2, varscan2
- FAM149B1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV54354733; called by muse, mutect2, varscan2
- FAM221B | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs778177155; called by muse, varscan2
- FAM228B | c.529+2T>G p.X177_splice | Splice Site (SNP) | VAF 39/112 reads (35%) | catalogued as rs1407748705; called by muse, mutect2, varscan2
- FAM8A1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1357945736; called by muse, mutect2, varscan2
- FASN | c.6481G>C p.E2161Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1140618; called by muse, mutect2
- FAT3 | c.4640G>C p.R1547T | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV53086326; called by muse, mutect2, varscan2
- FAT4 | c.9829G>A p.D3277N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs775681328, COSV58682001; called by muse, mutect2, varscan2
- FBN1 | c.7181G>A p.R2394Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs199750146, COSV57309156; called by muse, mutect2, varscan2
- FBN2 | c.6994G>A p.D2332N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.841); catalogued as rs886059894, COSV52495066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs772544895; called by muse, mutect2, varscan2
- FBXO38 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57026567; called by muse, mutect2
- FBXO42 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV65045232; called by muse, mutect2, varscan2
- FNBP4 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs202020703; called by muse, mutect2, varscan2
- FREM2 | c.7616T>G p.L2539R | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs764256362; called by muse, mutect2, varscan2
- FREM3 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs922764958, COSV61679111; called by muse, mutect2
- FSIP2 | c.16117G>A p.E5373K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58089216; called by muse, mutect2, varscan2
- GANC | c.2065G>A p.V689M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | PolyPhen benign (0.042); catalogued as rs1031278019, COSV58808840; called by muse, mutect2, varscan2
- GCKR | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as rs755683893; called by muse, mutect2, varscan2
- GCN1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV56107422; called by muse, mutect2
- GCOM1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360508274, COSV51099963; called by muse, mutect2, varscan2
- GOLGA4 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100729152; called by muse, mutect2, varscan2
- GOLGB1 | c.9641G>A p.R3214Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as rs773366766; called by muse, mutect2, varscan2
- GORASP2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs763981390; called by muse, mutect2, varscan2
- GPAT2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780124813; called by muse, mutect2, varscan2
- GPD2 | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV60095878; called by muse, mutect2, varscan2
- GPR62 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs1211942020, COSV59055416; called by muse, mutect2
- GPS2 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 6/141 reads (4%) | catalogued as COSV59748257, COSV59751338; called by muse, mutect2
- GRIP2 | c.3377G>A p.S1126N (on ENST00000619221; = p.S1029N on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99817424; called by muse, mutect2
- GRK2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs773756280, COSV57952903; called by muse, mutect2, varscan2
- GSG1 | c.623C>T p.S208F (on ENST00000651961 / NM_001080555.4; = p.L213= on NM_031289.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52196513; called by muse, mutect2, varscan2
- H2BC17 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV58153674; called by muse, mutect2, varscan2
- H2BC8 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); catalogued as COSV99773014; called by muse, mutect2, varscan2
- H3C11 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV58899154; called by muse, mutect2, varscan2
- HDAC7 | c.464C>G p.S155C (on ENST00000427332; = p.S194C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50318564; called by muse, mutect2, varscan2
- HES7 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as rs1341563215, COSV58555009; called by muse, mutect2
- HIP1R | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766621616, COSV53441598, COSV53442271; called by muse, mutect2, varscan2
- HMCN1 | c.13504G>C p.E4502Q | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV54894083; called by muse, mutect2, varscan2
- HMCN2 | c.11512G>A p.E3838K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs554164495, COSV52983647; called by muse, mutect2
- HNRNPA1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs1256552845; called by muse, mutect2, varscan2
- HS3ST5 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451126, COSV57135444; called by muse, mutect2, varscan2
- IGHV2-70 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs371123161; called by muse, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, varscan2
- IGKV4-1 | c.304A>C p.S102R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs539562219; called by muse, mutect2
- IGSF9B | c.3320C>G p.S1107W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as rs755766026, COSV100318262; called by muse, mutect2, varscan2
- IL21R | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs541619894, COSV61969850; called by muse, mutect2, varscan2
- IMP3 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59189813; called by muse, mutect2, varscan2
- IQCN | c.1936C>G p.H646D | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV66573169; called by muse, mutect2, varscan2
- IQGAP3 | c.4091G>A p.S1364N | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as COSV63252330; called by muse, mutect2
- IRF5 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50857089; called by muse, mutect2, varscan2
- IZUMO3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.12); catalogued as rs1401969792; called by muse, mutect2, varscan2
- JADE1 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99885349; called by muse, mutect2
- JCAD | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.372); catalogued as COSV64762071; called by muse, mutect2, varscan2
- KASH5 | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs749073038; called by muse, mutect2, varscan2
- KAT6B | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs370028079; called by muse, mutect2, varscan2
- KCNJ11 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56846454; called by muse, mutect2, varscan2
- KIAA0825 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV70247507; called by muse, mutect2
- KIFBP | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV62555590; called by muse, mutect2, varscan2
- KIRREL1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs1313745429; called by muse, mutect2
- KLHL18 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as rs116903383; called by muse, mutect2, varscan2
- KLK1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100032824; called by muse, mutect2, varscan2
- KMT2A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63288160; called by muse, mutect2, varscan2
- KMT2C | c.8530G>C p.E2844Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1222894668; called by muse, mutect2, varscan2
- KNL1 | c.5278G>A p.E1760K (on ENST00000346991 / NM_170589.5; = p.E1734K on NM_144508.5) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1277484750; called by muse, mutect2, varscan2
- KRIT1 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV60669053; called by muse, mutect2, varscan2
- KRT36 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60204225; called by muse, mutect2, varscan2
- KRT37 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs765476125; called by muse, mutect2, varscan2
- KRT37 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56657165; called by muse, mutect2, varscan2
- L3MBTL3 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62386548; called by muse, mutect2, varscan2
- LARS1 | c.724C>T p.P242S (on ENST00000394434 / NM_020117.11; = p.P215S on NM_016460.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV50986113; called by muse, mutect2, varscan2
- LCA5L | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV55743589; called by muse, mutect2
- LCT | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as rs1269974865, COSV104384153, COSV51557918; called by muse, mutect2, varscan2
- LINGO2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs1329891686, COSV58061180; called by muse, mutect2, varscan2
- LIPF | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV99490410; called by muse, mutect2
- LMAN2L | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99383702; called by muse, mutect2, varscan2
- LOXHD1 | c.5003G>A p.R1668Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.074); catalogued as rs572531886; called by muse, mutect2, varscan2
- LSM14A | c.608C>G p.S203* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV101471760; called by muse, mutect2, varscan2
- LTBP1 | c.2143G>A p.E715K (on ENST00000404816 / NM_206943.4; = p.E389K on NM_000627.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99062819; called by muse, mutect2, varscan2
- LZTR1 | c.2279G>A p.C760Y | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181002142; called by muse, mutect2
- MAGEC1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs757690163; called by muse, mutect2
- MAP3K1 | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 23/151 reads (15%) | catalogued as COSV68121789; called by muse, mutect2, varscan2
- MAP3K9 | c.2113C>G p.R705G (on ENST00000554752 / NM_001284230.1; = p.R719G on NM_033141.4) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV67122919; called by muse, mutect2, varscan2
- MAP4K3 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55719823; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.043); catalogued as rs1385329454; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCEE | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs757238704; called by muse, mutect2, varscan2
- MFSD6 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 133/389 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV55621248; called by muse, mutect2, varscan2
- MIA | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 20/265 reads (8%) | catalogued as COSV54570887; called by muse, mutect2
- MIEF2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs768409001; called by muse, mutect2, varscan2
- MIGA1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV100889812; called by muse, mutect2, varscan2
- MINAR1 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV59580743; called by muse, mutect2
- MIOS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100402528; called by muse, mutect2
- MKRN1 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV55436715; called by muse, varscan2
- MMAA | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1474274957; called by muse, mutect2, varscan2
- MMS22L | c.2835G>A p.M945I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51521703; called by muse, mutect2, varscan2
- MOS | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV61336304; called by muse, mutect2, varscan2
- MRPL46 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs776689846, COSV56900169; called by muse, mutect2, varscan2
- MUC12 | c.614C>T p.S205L (on ENST00000379442; = p.S62L on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as COSV65199219; called by muse, mutect2, varscan2
- MUC5AC | c.16589C>T p.S5530L | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); catalogued as rs1313071072; called by muse, mutect2, varscan2
- MYOCD | c.2506G>C p.D836H | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV58504495; called by muse, mutect2, varscan2
- NDUFA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs143476005; called by muse, mutect2, varscan2
- NFATC2 | c.2179C>G p.P727A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV65357328; called by muse, mutect2, varscan2
- NIBAN3 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1215540847; called by muse, mutect2, varscan2
- NKX1-1 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1223567025; called by muse, mutect2, varscan2
- NLRP1 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52557423; called by muse, mutect2
- NME5 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 107/306 reads (35%) | catalogued as COSV99497067; called by muse, mutect2, varscan2
- NODAL | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1380108149, COSV54661496; called by muse, mutect2, varscan2
- NPFFR1 | c.785C>G p.S262W | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53334450; called by muse, mutect2, varscan2
- NPSR1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV62198791; called by muse, mutect2, varscan2
- NR1D2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.387); catalogued as COSV100437446; called by muse, mutect2, varscan2
- NRARP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV63082886, COSV63083075; called by muse, mutect2
- NSUN6 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763020178, COSV56618570, COSV99995279; called by muse, mutect2, varscan2
- NT5DC4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293295520; called by muse, mutect2, varscan2
- NTAN1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.082); catalogued as rs200102960, COSV55074955; called by mutect2, varscan2
- NUFIP1 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193195732; called by muse, mutect2, varscan2
- OBSCN | c.5137+3C>T | Splice Region (SNP) | VAF 21/90 reads (23%) | catalogued as rs531852366; called by muse, mutect2, varscan2
- OGDH | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV56054395; called by muse, mutect2
- OR10H4 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV100437654; called by muse, mutect2, varscan2
- OR9G4 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57249377; called by muse, mutect2, varscan2
- OTOA | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV53766416; called by muse, mutect2, varscan2
- P2RX1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV50113893; called by muse, mutect2, varscan2
- PAH | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs868854935, COSV61013953; called by muse, mutect2, varscan2
- PALLD | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV54994296; called by muse, mutect2, varscan2
- PAPLN | c.2071G>A p.G691R (on ENST00000554301; = p.G664R on NM_173462.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs773393825, COSV53712897; called by mutect2, varscan2
- PAPPA | c.3274C>T p.Q1092* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100072818, COSV100073108; called by muse, mutect2, varscan2
- PARD3 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs1234358017, COSV60749222; called by muse, mutect2, varscan2
- PBRM1 | c.3678G>A p.M1226I (on ENST00000296302 / NM_001366071.2; = p.M1201I on NM_018313.5) | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as COSV56302802; called by muse, mutect2
- PC | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs193271416, COSV58992105; called by muse, mutect2, varscan2
- PCDHB8 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 53/699 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs146359786; called by muse, mutect2
- PCDHGB3 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV53981839; called by muse, mutect2
- PCGF1 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99029100; called by muse, mutect2
- PCLO | c.6299G>A p.R2100K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61640661; called by muse, mutect2, varscan2
- PCM1 | c.3219G>A p.Q1073= | Splice Region (SNP) | VAF 34/110 reads (31%) | catalogued as COSV100278904; called by muse, mutect2, varscan2
- PDZD2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56854542, COSV56857152; called by muse, mutect2, varscan2
- PGBD4 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs779125361; called by muse, mutect2, varscan2
- PIK3C2G | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.269); catalogued as rs760928254, COSV56812247, COSV56839244; called by muse, mutect2
- PIK3C2G | c.2905C>T p.Q969* (on ENST00000676171; = p.Q928* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV56816769; called by muse, mutect2, varscan2
- PLA2G4A | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV66555487; called by muse, mutect2, varscan2
- PNP | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV64092057; called by muse, mutect2, varscan2
- PNPLA7 | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.092); catalogued as rs762980119, COSV52996220; called by muse, mutect2, varscan2
- POM121 | c.982G>A p.E328K (on ENST00000434423; = p.E63K on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1342475666, COSV57513989; called by muse, mutect2, varscan2
- PPP1R18 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs773868877; called by muse, mutect2, varscan2
- PPP1R3A | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV52885352; called by muse, mutect2, varscan2
- PPP6R1 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs748962055; called by muse, mutect2, varscan2
- PRKAA2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV64803540; called by muse, mutect2, varscan2
- PRKD2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52189638; called by muse, mutect2, varscan2
- PRPH | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as rs1224101129; called by muse, mutect2, varscan2
- PRUNE2 | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | catalogued as COSV65049207; called by muse, mutect2, varscan2
- PSMC4 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50096954; called by muse, mutect2, varscan2
- PSTPIP1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs781437901; called by muse, mutect2, varscan2
- PTGFRN | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468830169; called by muse, mutect2, varscan2
- PTGIR | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.257); catalogued as rs1304857139; called by muse, mutect2, varscan2
- PTPN18 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as rs751093914, COSV51559943; called by muse, mutect2, varscan2
- PTPN22 | c.1423C>A p.Q475K (on ENST00000359785 / NM_001193431.2; = p.Q420K on NM_012411.5) | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV63085010; called by muse, mutect2, varscan2
- PYGB | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99404904; called by muse, mutect2, varscan2
- RABEP2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1159753921; called by muse, mutect2, varscan2
- RABGEF1 | c.1432C>G p.Q478E (on ENST00000439720 / NM_001287061.2; = p.Q465E on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1176926995; called by muse, mutect2, varscan2
- RANBP2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1558919808; called by muse, mutect2, varscan2
- RBFOX1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV60952754; called by muse, mutect2, varscan2
- RBM12 | c.1507C>A p.H503N | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV58290906, COSV58291694; called by muse, mutect2, varscan2
- RELCH | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56887732; called by muse, mutect2, varscan2
- RELN | c.10337G>A p.R3446K | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV59022696; called by muse, mutect2
- REM2 | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 48/83 reads (58%) | catalogued as COSV99944584; called by muse, varscan2
- REV3L | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs748286892, COSV62621278; called by muse, mutect2, varscan2
- RFC3 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV66296508; called by muse, mutect2
- RHOT2 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as rs565061375; called by muse, mutect2, varscan2
- RNF214 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); catalogued as COSV100326548; called by muse, mutect2, varscan2
- RNF40 | c.1754C>G p.S585C | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV61214663; called by muse, mutect2, varscan2
- ROBO3 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs556647372, COSV67299288; called by muse, mutect2, varscan2
- ROCK2 | c.1863C>G p.I621M | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs935995814; called by muse, mutect2, varscan2
- ROR1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs1414634654; called by muse, mutect2
- ROR2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.202); catalogued as rs761854477, COSV65218280; called by muse, mutect2
- RP1 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV55124112; called by muse, mutect2, varscan2
- RP1 | c.878del p.S293Ffs*10 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as COSV55128407; called by mutect2, pindel, varscan2
- RTEL1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100542875; called by muse, mutect2, varscan2
- RYR1 | c.10389G>C p.E3463D | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV62108953; called by muse, mutect2, varscan2
- RYR1 | c.12335C>T p.S4112L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs193922847, CM071983, COSV62087989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.675); catalogued as COSV63720620; called by muse, mutect2
- S1PR3 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63980993; called by muse, mutect2, varscan2
- SCN10A | c.4736G>C p.R1579P | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71862155, COSV71862173; called by muse, mutect2, varscan2
- SCN3A | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as rs1553535085; called by muse, mutect2
- SCN8A | c.4819G>C p.E1607Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); catalogued as COSV61981969, COSV61982036; called by muse, mutect2, varscan2
- SDC1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322835586; called by muse, mutect2, varscan2
- SFTPC | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100109154, COSV100110239; called by muse, mutect2, varscan2
- SGF29 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs766477106, COSV57682925; called by muse, mutect2, varscan2
- SH2D4A | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56122242; called by muse, mutect2, varscan2
- SKOR2 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.497); catalogued as rs896692419; called by muse, mutect2, varscan2
- SLC22A10 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750659598, COSV100235855; called by muse, mutect2, varscan2
- SLC35G3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.017); catalogued as COSV99268315; called by muse, mutect2, varscan2
- SLC38A2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs939907883; called by muse, mutect2, varscan2
- SLC7A14 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1222445339; called by muse, mutect2, varscan2
- SLC9A4 | c.1095G>C p.L365F | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54830046, COSV54835714; called by muse, mutect2, varscan2
- SLFN12L | c.1205C>G p.S402* (on ENST00000260908 / NM_001363830.1; = p.S420* on NM_001195790.1) | Nonsense Mutation (SNP) | VAF 68/278 reads (24%) | catalogued as COSV99609873; called by muse, mutect2, varscan2
- SMG6 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs145406772; called by muse, mutect2, varscan2
- SMIM15 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as rs1421279114, COSV100171292; called by muse, mutect2, varscan2
- SNRNP40 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99744961; called by muse, mutect2, varscan2
- SORBS2 | c.2815G>A p.E939K (on ENST00000284776 / NM_021069.5; = p.E505K on NM_003603.6) | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV53000000; called by muse, mutect2, varscan2
- SORBS2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as rs762729043, COSV52995480; called by muse, mutect2, varscan2
- SP140 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1196054980; called by muse, mutect2, varscan2
- SPAG4 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 4/73 reads (5%) | catalogued as COSV65330056; called by muse, mutect2
- SPCS3 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280351513; called by muse, mutect2
- SPHKAP | c.4579G>T p.E1527* | Nonsense Mutation (SNP) | VAF 54/159 reads (34%) | catalogued as COSV100763946, COSV60893637; called by muse, mutect2, varscan2
- SPNS1 | c.1386C>G p.F462L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57955558; called by muse, mutect2
- SPRTN | c.1053G>T p.R351S | Missense Mutation (SNP) | VAF 189/514 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV50478428; called by muse, mutect2, varscan2
- SSX2IP | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs199662991; called by muse, mutect2, varscan2
- ST18 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52489120; called by muse, mutect2
- ST6GALNAC5 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 42/110 reads (38%) | PolyPhen benign (0.038); catalogued as rs779734543; called by muse, mutect2, varscan2
- STK40 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.931); catalogued as rs747374387; called by muse, mutect2, varscan2
- STOX1 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 119/445 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs757572204; called by muse, mutect2, varscan2
- SWT1 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100833130; called by muse, mutect2
- SYNPO2 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100205465; called by muse, mutect2, varscan2
- TAOK1 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99915008; called by muse, mutect2, varscan2
- TBC1D22A | c.1349C>G p.S450C | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV61439436; called by muse, mutect2, varscan2
- TC2N | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 67/206 reads (33%) | catalogued as COSV61747492; called by muse, mutect2
- TCHH | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as rs1436628435; called by muse, mutect2
- TERF2IP | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as rs150990220; called by muse, varscan2
- TEX9 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as rs1373252046; called by muse, mutect2, varscan2
- TFPI2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as rs770380317, COSV55990401, COSV55992087; called by muse, mutect2, varscan2
- TIMP4 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); catalogued as rs746718077; called by muse, mutect2, varscan2
- TLR3 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs886503355; called by muse, mutect2, varscan2
- TLR6 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV67935026; called by muse, mutect2
- TM7SF3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.06); catalogued as rs1264459708; called by muse, mutect2, varscan2
- TMEM53 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62408427; called by muse, mutect2, varscan2
- TNFRSF12A | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.02); catalogued as rs752145330; called by muse, mutect2, varscan2
- TNFRSF13C | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs776189874, COSV52169225, COSV99351674, COSV99351810; called by muse, mutect2, varscan2
- TNR | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV54886381; called by muse, mutect2, varscan2
- TPRKB | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99721717; called by muse, mutect2, varscan2
- TRIM21 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54343913; called by muse, mutect2, varscan2
- TRIM28 | c.723-5C>G | Splice Region (SNP) | VAF 50/185 reads (27%) | catalogued as rs369366788; called by muse, mutect2, varscan2
- TRPV4 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs1024730803; called by muse, mutect2, varscan2
- TRRAP | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV62838897; called by muse, mutect2, varscan2
- TTC30B | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV68809266, COSV68809725; called by muse, mutect2, varscan2
- TTC8 | c.1021C>T p.H341Y (on ENST00000338104 / NM_001288781.1; = p.H325Y on NM_144596.4) | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV57628961; called by muse, mutect2, varscan2
- TTN | c.81698G>A p.G27233E (on ENST00000591111; = p.G19809E on NM_003319.4) | Missense Mutation (SNP) | VAF 44/123 reads (36%) | PolyPhen probably damaging (1); catalogued as COSV100615592, COSV60069633; called by muse, mutect2, varscan2
- TTN | c.81184C>G p.Q27062E (on ENST00000591111; = p.Q19638E on NM_003319.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | PolyPhen benign (0.053); catalogued as COSV100619125; called by muse, mutect2, varscan2
- TTYH2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146608677; called by muse, mutect2
- TUBB2A | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.94); catalogued as COSV61319210; called by muse, mutect2
- UCKL1 | c.1567+3G>A | Splice Region (SNP) | VAF 47/116 reads (41%) | catalogued as rs752516222; called by muse, mutect2, varscan2
- USP38 | c.2759G>A p.R920K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61025106; called by muse, mutect2
- UTY | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58872926; called by muse, mutect2, varscan2
- VPS13D | c.6328C>G p.L2110V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV50681720; called by muse, mutect2
- VPS18 | c.2373C>G p.F791L | Missense Mutation (SNP) | VAF 115/318 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55029339; called by muse, mutect2, varscan2
- WBP4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1413849328; called by muse, mutect2
- WDR26 | c.1150G>T p.D384Y (on ENST00000414423 / NM_001379403.1; = p.D284Y on NM_025160.7) | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54357117; called by muse, mutect2
- WDR27 | c.573G>C p.Q191H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61218834; called by muse, mutect2, varscan2
- WDTC1 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.217); catalogued as rs1241014844, COSV60089763; called by muse, mutect2, varscan2
- WIF1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201325270, COSV54131027; called by muse, mutect2, varscan2
- XIRP1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs1349722946, COSV61139848; called by muse, mutect2
- XYLT2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1471762134, COSV50017993; called by muse, mutect2, varscan2
- YARS2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.185); catalogued as rs1427613958, COSV61402213, COSV61402395; called by muse, mutect2, varscan2
- YJEFN3 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53065489; called by muse, mutect2
- YLPM1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.234); catalogued as COSV53112823; called by muse, mutect2
- ZEB2 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560606965, COSV100357358; called by muse, mutect2, varscan2
- ZFP14 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV54201303, COSV99525110; called by muse, mutect2, varscan2
- ZFP64 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as rs1168631095, COSV53798307; called by muse, mutect2, varscan2
- ZNF107 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV61327077; called by muse, mutect2, varscan2
- ZNF221 | c.1455G>C p.K485N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777129718; called by muse, mutect2, varscan2
- ZNF267 | c.1751C>A p.S584Y | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV56251489; called by muse, mutect2, varscan2
- ZNF430 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55109853; called by muse, mutect2, varscan2
- ZNF436 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1350301166, COSV58358998; called by muse, mutect2, varscan2
- ZNF443 | c.1411C>G p.H471D | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759313325, COSV56890574; called by muse, mutect2
- ZNF48 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100198078; called by muse, mutect2
- ZNF561 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.894); catalogued as COSV100254384; called by muse, mutect2, varscan2
- ZNF570 | c.1317G>C p.E439D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375705755; called by muse, mutect2, varscan2
- ZNF600 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100593001; called by muse, mutect2, varscan2
- ZNF607 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as rs753791549, COSV67696376; called by muse, mutect2, varscan2
- ZNF630 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52097772, COSV99332547; called by muse, mutect2, varscan2
- ZNF700 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.973); catalogued as rs564139573, COSV54316104; called by muse, mutect2, varscan2
- ZNF93 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as rs1197422261; called by muse, mutect2, varscan2
- ZPBP | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99248709; called by muse, mutect2
- AATK | c.2996C>G p.S999* (on ENST00000326724 / NM_001080395.3; = p.S896* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- ABCA9 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ABL1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- AC026786.1 | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.27); called by muse, mutect2
- AC092143.1 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- AC097637.1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- ACCSL | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- ADAL | c.815C>A p.S272Y (on ENST00000562188 / NM_001324366.2; = p.S245Y on NM_001159280.3) | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADAM11 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- ADAM29 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 58/185 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADAMTS9 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL1 | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ADGRL2 | c.203A>C p.D68A | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.481A>C p.N161H (on ENST00000506720 / NM_001322402.2; = p.N93H on NM_015236.6) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADH5 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFAP1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGRN | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AK9 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP13 | c.6395C>T p.S2132L (on ENST00000394518 / NM_007200.5; = p.S2136L on NM_006738.6) | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- AKAP3 | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- AKNA | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); called by muse, varscan2
- AKTIP | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AL096814.1 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- AMBRA1 | c.1997G>A p.R666K (on ENST00000458649 / NM_001367468.1; = p.R576K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ANAPC4 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ANGPTL3 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANKRD2 | c.398C>G p.S133W | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, varscan2
- ANLN | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANO1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANO8 | c.2928G>A p.M976I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- AP1M2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2
- AP3B2 | c.2367G>C p.W789C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- APC2 | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP1 | c.1586C>T p.A529V (on ENST00000393609 / NM_001040118.2; = p.A284V on NM_015242.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ARHGAP32 | c.1390G>A p.E464K (on ENST00000310343 / NM_001378025.1; = p.E115K on NM_014715.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ARHGAP5 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARL14EP | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ARMC8 | c.1792G>A p.D598N (on ENST00000469044 / NM_001363941.2; = p.D584N on NM_015396.6) | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2
- ARTN | c.94C>G p.L32V (on ENST00000372354; = p.L40V on NM_057090.2) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ATMIN | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ATP2A3 | c.2613G>T p.R871S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN10 | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN7 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- AXDND1 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.149); called by muse, mutect2
- BBOX1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BBS10 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- BCL6 | c.161+3G>T | Splice Region (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- BHMG1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- BHMT | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); called by muse, mutect2
- BICD2 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BIRC6 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- BNC2 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- BTBD6 | c.215+3G>A | Splice Region (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- BTBD7 | c.1458A>C p.L486F | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C10orf90 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- C12orf45 | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- C15orf65 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- C16orf46 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- C17orf49 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C18orf21 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- C2orf16 | c.5357C>T p.S1786L | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- C3 | c.4546+3G>A | Splice Region (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- CACNA1A | c.6860G>C p.R2287P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CACNA1B | c.2935C>T p.H979Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CACNA1G | c.2956C>T p.Q986* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | called by muse, varscan2
- CAMSAP2 | c.3580C>A p.Q1194K (on ENST00000236925 / NM_001297707.2; = p.Q1183K on NM_203459.3) | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2
- CAMSAP2 | c.3892G>A p.D1298N (on ENST00000236925 / NM_001297707.2; = p.D1287N on NM_203459.3) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CBLC | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCDC14 | c.2632A>C p.T878P (on ENST00000488653; = p.T830P on NM_022757.5) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC170 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC30 | c.2261C>T p.S754L (on ENST00000340612; = p.S711L on NM_001080850.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC81 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CD37 | c.342+3G>T | Splice Region (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- CDC42 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CDCA2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CDK20 | c.75+3G>T | Splice Region (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.1104G>A p.M368I (on ENST00000357886 / NM_001365728.1; = p.M354I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); called by muse, mutect2
- CDKL5 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CELSR3 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEMIP2 | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CEP104 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CEP126 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP170 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEP192 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CEP350 | c.8776C>G p.L2926V | Missense Mutation (SNP) | VAF 133/336 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CFAP43 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2
- CHAF1A | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHGB | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 21/341 reads (6%) | called by muse, mutect2
- CIP2A | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2
- CLEC12B | c.410-3C>T | Splice Region (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- CLEC4F | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLIP1 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNBD1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CNTNAP2 | c.2563G>T p.E855* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- COL6A5 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- COL7A1 | c.8037C>G p.I2679M | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- COL7A1 | c.7295G>C p.R2432T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CPSF4L | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- CR1L | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CREB5 | c.1410G>T p.Q470H (on ENST00000357727 / NM_182898.4; = p.Q463H on NM_004904.3) | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CREBZF | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CSMD2 | c.6110G>C p.R2037T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CTTNBP2 | c.4966G>A p.E1656K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCHS2 | n.231G>A | Splice Region (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- DDB1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- DENND2D | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DEPDC5 | c.413+4G>A | Splice Region (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- DHX40 | c.567G>T p.L189F | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- DMD | c.9650-1G>A p.X3217_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- DNAH14 | c.5911G>C p.D1971H (on ENST00000445597; = p.D2511H on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.7522C>G p.Q2508E (on ENST00000445597; = p.Q3280E on NM_001367479.1) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, mutect2
- DNAH6 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAH6 | c.2000G>C p.R667T | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DNAJC13 | c.2739G>C p.L913F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DOCK5 | c.3178C>G p.Q1060E | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- DOK5 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- DOP1A | c.6994G>C p.D2332H | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOP1B | c.6351G>A p.L2117= | Splice Region (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- DPYD | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- DSC1 | c.1209C>A p.F403L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DSPP | c.3751G>A p.D1251N | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DST | c.18248C>A p.S6083* (on ENST00000361203 / NM_001374722.1; = p.S3780* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- DTX3L | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DVL2 | c.1874C>G p.S625C | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DXO | c.798G>T p.W266C | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DYNC1H1 | c.7150A>G p.S2384G | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC2LI1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- EGFR | c.1207+5G>C | Splice Region (SNP) | VAF 53/216 reads (25%) | called by muse, mutect2, varscan2
- ELF1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ENDOV | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- EP400 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- EPC2 | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- EPG5 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- EPHX2 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ERAP2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ERBB4 | c.3772T>A p.Y1258N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ERCC4 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ESYT1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- ETFBKMT | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2
- ETFDH | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ETNPPL | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOSC10 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EXOSC5 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 57/237 reads (24%) | called by muse, mutect2, varscan2
- FAIM | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2
- FAM166A | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171A2 | c.2410G>C p.E804Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FAM193B | c.393G>C p.Q131H | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FASTK | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAT4 | c.4649T>G p.I1550S | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FBH1 | c.2793G>C p.M931I (on ENST00000362091 / NM_178150.3; = p.M982I on NM_032807.4) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FBXO10 | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXW10 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 77/219 reads (35%) | called by muse, mutect2, varscan2
- FCER1G | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.07); called by muse, mutect2
- FIGNL2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.147); called by muse, mutect2
- FKBP5 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- FLG2 | c.3440G>C p.R1147T | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FNBP4 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- FNDC1 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2
- FNDC3B | c.3265C>A p.L1089M | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOXN3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- FSCN1 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- FSIP2 | c.14009C>G p.S4670* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- FSTL4 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FZD5 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABPB2 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GABRP | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNTL5 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- GAS1 | c.989G>A p.W330* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GMNN | c.267G>C p.M89I | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- GPCPD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 72/224 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GPR158 | c.3398A>C p.N1133T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GPR22 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2
- GRIN2B | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GSG1L2 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTF2A1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- GTF2IRD2 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H2AJ | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HDAC7 | c.605G>A p.S202N (on ENST00000427332; = p.S241N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HECTD1 | c.7550+7G>A | Splice Region (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- HECTD2 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELQ | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- HEMGN | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HERPUD2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HGSNAT | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HIVEP1 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- HIVEP2 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- HMX2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- HSP90AB1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ICAM5 | c.2270G>T p.G757V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ID2 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IFFO1 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IFRD1 | c.1329G>C p.K443N | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFT80 | c.947G>C p.R316T | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IGF2R | c.2709C>G p.I903M | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- IGHV2-70 | c.290del p.N97Tfs*7 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- IGHV2-70 | c.129_157del p.S44Vfs*20 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- IGHV2-70D | c.155_156delinsT p.G52Vfs*4 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | called by pindel, varscan2*
- IGSF9B | c.3319T>A p.S1107T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IL17REL | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ITGA2 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- JMJD1C | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KBTBD2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNC1 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCP | c.3942C>G p.V1314= (on ENST00000620378; = p.V1438= on NM_001366122.1) | Splice Region (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- KCTD12 | c.425C>A p.S142* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- KDM3B | c.193-1G>A p.X65_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- KDM3B | c.2953G>C p.E985Q | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KIAA1522 | c.2773G>A p.E925K (on ENST00000373480 / NM_001198972.2; = p.E984K on NM_020888.3) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIAA2026 | c.2122C>T p.H708Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- KIF1B | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF27 | c.3319G>A p.V1107I | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF4B | c.2422C>G p.Q808E | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KPRP | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KRBA2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2
- KRT6B | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2
- L3MBTL3 | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LARS1 | c.2362C>T p.P788S (on ENST00000394434 / NM_020117.11; = p.P761S on NM_016460.3) | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHFPL1 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LHX5 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LIN9 | c.1047G>C p.E349D (on ENST00000366808 / NM_001270410.2; = p.E294D on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- LKAAEAR1 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LLGL1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LPIN1 | c.2065C>G p.L689V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LRP1 | c.7375G>A p.D2459N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRC42 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2
- LRRC42 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | called by muse, mutect2, varscan2
- LSG1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LST1 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 128/343 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- LTBR | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LTK | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- LZTR1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- LZTS3 | c.2005G>C p.E669Q (on ENST00000329152; = p.E623Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MACIR | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MAGED2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MAP2K2 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAP3K10 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- MAP3K20 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.334); called by muse, mutect2
- MAP4 | c.2869G>C p.E957Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAST4 | c.3231G>C p.K1077N (on ENST00000403625 / NM_001164664.2; = p.K888N on NM_015183.3) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MBLAC1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by mutect2, varscan2
- MDC1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MDFIC | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- MDN1 | c.7486G>A p.E2496K | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- METAP2 | c.966G>A p.V322= | Splice Region (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- METTL18 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- METTL2A | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- MFSD6 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.185); called by muse, mutect2
- MFSD6L | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MKRN1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, varscan2
- MLLT3 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MOK | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2
- MRPL37 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTARC2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MTCH2 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- MTHFD1L | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MUC13 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC17 | c.7684A>T p.T2562S | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYBL1 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- MYBL2 | c.1296C>A p.F432L | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYH11 | c.2460G>C p.Q820H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH14 | c.3609G>C p.E1203D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2
- MYH15 | c.5254G>C p.E1752Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYH8 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- MYH9 | c.4530G>A p.M1510I | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYLK4 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYO15A | c.2554G>A p.G852R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYO1A | c.2877+5C>T | Splice Region (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- MYO5B | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- MYO9A | c.7447G>T p.D2483Y | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NCKAP1 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NDC1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 57/180 reads (32%) | called by muse, mutect2, varscan2
- NECAP2 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NEIL3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NEK9 | c.936G>A p.R312= | Splice Region (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- NELFCD | c.1129G>A p.E377K (on ENST00000602795; = p.E359K on NM_198976.4) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NFATC2IP | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFE2L1 | c.87T>G p.D29E | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NID1 | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NOTCH2 | c.6436G>A p.V2146I | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NRAP | c.4528C>A p.L1510M (on ENST00000359988 / NM_001322945.2; = p.L1475M on NM_006175.4) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NRG4 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NSD2 | c.2395C>A p.L799M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NT5DC4 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NUDT18 | c.804C>G p.I268M | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- NUP210 | c.5640G>A p.W1880* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- NWD2 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2
- NXPE2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 37/121 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR2B3 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2
- ORC1 | c.2392-1G>C p.X798_splice | Splice Site (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- ORM2 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OTP | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OTUB2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2
- OVCH1 | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- PARP15 | c.1684G>C p.D562H (on ENST00000464300 / NM_001113523.3; = p.D328H on NM_152615.2) | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PAX9 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 71/132 reads (54%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PCDHGA9 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDE2A | c.757-3C>T | Splice Region (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PEAK1 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PHKG1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIK3R3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PIK3R4 | c.1837T>G p.S613A | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PIP4K2A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PKD1L1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- PLCG1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PLOD2 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PM20D1 | c.1385+3G>A | Splice Region (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- PNLIPRP1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLR2F | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, varscan2
- POLR2F | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, varscan2
- POLR3E | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARA | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PPM1K | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPM1K | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2
- PPP1R13L | c.2470C>G p.Q824E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- PPP1R9B | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PRKD2 | c.2121C>A p.F707L | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PRKX | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF40B | c.2318-4C>G | Splice Region (SNP) | VAF 52/397 reads (13%) | called by muse, mutect2, varscan2
- PSD3 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2
- PSORS1C1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.452C>T p.S151F (on ENST00000421990 / NM_001136042.2; = p.S133F on NM_025267.3) | Missense Mutation (SNP) | VAF 6/178 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PTP4A1 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- PTRH2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUS7 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PUS7 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- PXDN | c.4192G>C p.D1398H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.235); called by muse, mutect2
- R3HCC1L | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- RAD1 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RAG1 | c.2771C>T p.S924F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASAL2 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RASGRF2 | c.2823G>A p.M941I | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RASSF6 | c.235G>A p.G79R (on ENST00000342081 / NM_201431.2; = p.G47R on NM_177532.5) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RBP4 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2
- RCN3 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, varscan2
- RECQL5 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- REM2 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFLNA | c.270C>G p.F90L (on ENST00000546355 / NM_001365156.1; = p.F9L on NM_181709.4) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RFX4 | c.1703A>G p.N568S (on ENST00000392842 / NM_213594.3; = p.N474S on NM_032491.6) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFXAP | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- RHOJ | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- RING1 | c.943del p.E315Sfs*61 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- RNF139 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF139 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- RNF216 | c.2056G>A p.E686K (on ENST00000425013 / NM_207116.3; = p.E743K on NM_207111.4) | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ROBO1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ROBO2 | c.-13-1G>A | Splice Site (SNP) | VAF 107/312 reads (34%) | called by muse, mutect2, varscan2
- ROMO1 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- RPS13 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2
- RPS6KA1 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RTF1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.038); called by muse, varscan2
- SACM1L | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAFB2 | c.2807T>A p.V936D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SARDH | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- SCAF8 | c.875C>G p.S292* | Nonsense Mutation (SNP) | VAF 59/155 reads (38%) | called by muse, mutect2, varscan2
- SCARF1 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SEC61A1 | c.9C>G p.I3M | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- SEMA5A | c.2312A>G p.D771G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, varscan2
- SERTAD4 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETDB2 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFPQ | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SFSWAP | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- SH3PXD2B | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHPRH | c.4363G>T p.E1455* (on ENST00000275233 / NM_001042683.3; = p.E1459* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC12A1 | c.2874-1G>A p.X958_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SLC13A4 | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC14A2 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SLC16A6 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC17A3 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC22A25 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.034); called by muse, mutect2
- SLC25A1 | c.302+3G>A | Splice Region (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- SLC29A4 | c.72G>C p.M24I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); called by muse, mutect2
- SLC30A2 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC37A3 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- SLC45A2 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SLC8A1 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SLC9A7 | c.1671C>T p.F557= | Splice Region (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- SLITRK2 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK6 | c.1993A>C p.T665P | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SLTM | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMG7 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, mutect2, varscan2
1,617 further variants in this file (102 protein-altering or splice-affecting, 377 silent, 1,138 other) are not listed here.
